Somatic mutation profile of tumor specimen TCGA-D8-A1JU-01A (aliquot TCGA-D8-A1JU-01A-11D-A13L-09) from TCGA case TCGA-D8-A1JU, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 51.3 years (18,733 days).
Specimen TCGA-D8-A1JU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bee7f5e-e1b6-42e5-80d7-51f293f0976e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1JU-10A (Blood Derived Normal), aliquot TCGA-D8-A1JU-10A-01D-A188-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39d696cc-b038-49ab-a299-c673bbce1d2d

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ATP7A | c.349A>G p.K117E | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV100431397; called by muse, mutect2
- COPS4 | c.410+1G>A p.X137_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | catalogued as COSV52316532; called by muse, mutect2, varscan2
- FAM47B | c.1696C>A p.P566T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.41); catalogued as COSV61455985; called by muse, mutect2, varscan2
- HMCN1 | c.5039T>C p.V1680A | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.243); catalogued as COSV99633455; called by muse, mutect2, varscan2
- HS3ST4 | c.896C>G p.T299R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58820828, COSV58825806; called by muse, mutect2, varscan2
- PCDHA3 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.502); catalogued as rs1467501869, COSV63543775; called by muse, mutect2
- POLA1 | c.2960C>T p.T987M | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100985700, COSV66887371; called by muse, mutect2
- RNASEL | c.1090T>C p.F364L | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV100842628; called by muse, mutect2, varscan2
- TNFRSF11B | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as rs760601102, COSV52072602; called by muse, mutect2, varscan2
- MAP3K1 | c.819_820del p.R273Sfs*27 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- APOB | c.6345G>A p.L2115= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV51946393; called by muse, mutect2, varscan2
- DROSHA | c.1089T>A p.A363= | Silent (SNP) | VAF 5/101 reads (5%) | catalogued as COSV100757757; called by muse, mutect2
- LAX1 | c.444A>T p.T148= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV65849874; called by muse, mutect2, varscan2
- MYCBP2 | c.5382C>T p.R1794= (on ENST00000357337; = p.R1832= on NM_015057.5) | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV62020806; called by muse, mutect2, varscan2
- PCDHGA9 | c.1822C>T p.L608= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as COSV54002728; called by muse, mutect2, varscan2
- SYT9 | c.165G>A p.L55= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as COSV59622926; called by muse, mutect2, varscan2
